Somatic mutation profile of tumor specimen TCGA-D1-A1NS-01A (aliquot TCGA-D1-A1NS-01A-11D-A14G-09) from TCGA case TCGA-D1-A1NS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 53.8 years (19,638 days).
Specimen TCGA-D1-A1NS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec1a38ea-051e-4704-b1b9-5df6752763f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1NS-10A (Blood Derived Normal), aliquot TCGA-D1-A1NS-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/224bc9d3-89a5-4548-bc80-f642fc85e318

The open-access MAF lists 335 somatic variants for this specimen: 257 protein-altering or splice-affecting, 75 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 75, Frame Shift Del 53, Nonsense Mutation 11, Frame Shift Ins 11, In Frame Del 6, Splice Region 4, Nonstop Mutation 2, Splice Site 2, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.1027-2A>T p.X343_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | hotspot (GDC flag); catalogued as CS090868, CS110214, COSV64293079, COSV64296375; called by muse, mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCB11 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV99791976; called by muse, mutect2, varscan2
- ADAM30 | c.1865del p.N622Ifs*71 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs750058585; called by mutect2, varscan2
- ADAMTSL5 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs766069046, COSV57860124; called by muse, mutect2, varscan2
- AKAP17A | c.1465G>T p.G489C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100002131; called by muse, mutect2, varscan2
- ANO8 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV99344340; called by muse, mutect2, varscan2
- AP2M1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99490513; called by muse, mutect2
- AP3B2 | c.2638G>T p.D880Y (on ENST00000261722; = p.D874Y on NM_004644.5) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99916336; called by muse, mutect2, varscan2
- APOBR | c.1601G>A p.S534N (on ENST00000431282; = p.S543N on NM_018690.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.234); catalogued as COSV100112471; called by muse, mutect2, varscan2
- ARHGEF11 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs760350447, COSV59352833; called by muse, mutect2, varscan2
- ARHGEF17 | c.1940G>A p.G647D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99735382; called by muse, mutect2, varscan2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARID1A | c.6475A>T p.K2159* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100251245; called by muse, mutect2, varscan2
- ARL4A | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100775904; called by muse, mutect2, varscan2
- ASB13 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764527518, COSV100731350; called by muse, mutect2, varscan2
- ATF7IP2 | c.1312del p.I438Lfs*21 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs763946306; called by mutect2, pindel, varscan2
- ATM | c.9171A>T p.*3057Cext*29 | Nonstop Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV53745904, COSV99589161; called by muse, mutect2, varscan2
- ATP2A3 | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99989056; called by muse, mutect2
- ATP8B4 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs528390895, COSV52709701; called by muse, mutect2, varscan2
- BCAS3 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs377752373; called by muse, mutect2, varscan2
- BCL6 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV51656118; called by muse, mutect2, varscan2
- BRAP | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs745860025, COSV100554089; called by muse, mutect2, varscan2
- BTN3A1 | c.343_345del p.N115del | In Frame Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs1329386502; called by mutect2, pindel, varscan2
- C6orf58 | c.797T>C p.M266T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100314844, COSV61667625; called by muse, mutect2, varscan2
- C8orf82 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs1212694671, COSV99430881; called by muse, mutect2, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs201838505; called by mutect2, varscan2
- CAND1 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV101607313; called by muse, mutect2, varscan2
- CARD6 | c.1379T>C p.L460P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99620658; called by muse, mutect2, varscan2
- CARD9 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772249417, COSV53738140; called by muse, mutect2, varscan2
- CBX1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99848117; called by muse, mutect2, varscan2
- CC2D1B | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145750942; called by muse, mutect2, varscan2
- CCER1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.176); catalogued as rs767277765, COSV100727008; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDAN1 | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369919247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC25B | c.1098T>C p.P366= (on ENST00000245960 / NM_021873.3; = p.P352= on NM_004358.4) | Splice Region (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99847829; called by muse, mutect2, varscan2
- CDKL4 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101115229; called by muse, mutect2, varscan2
- CENPS-CORT | c.485_487del p.S162del | In Frame Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs772618348; called by pindel, varscan2
- CERCAM | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs374569794; called by muse, mutect2, varscan2
- CHD2 | c.5243G>A p.R1748H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1377813463, COSV67706691; called by muse, mutect2
- CHERP | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99550184; called by muse, mutect2
- CHST12 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99324422; called by muse, mutect2
- CNTFR | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.025); catalogued as rs1221255412, COSV100667517; called by muse, mutect2, varscan2
- COL12A1 | c.6893C>T p.P2298L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469257746, COSV100485814, COSV100486058; called by muse, mutect2, varscan2
- COL9A3 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV59655811; called by muse, mutect2, varscan2
- COPB1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV99999482; called by muse, mutect2, varscan2
- COPS6 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57997896; called by muse, mutect2
- CSMD3 | c.10588G>A p.A3530T (on ENST00000297405 / NM_001363185.1; = p.A3361T on NM_052900.3) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs750533886, COSV52243421; called by muse, mutect2, varscan2
- CYB5D2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV100028919; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as COSV99245498; called by mutect2, varscan2
- DICER1 | c.5439G>T p.E1813D | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as CM160049, COSV58615264, COSV58615771; called by muse, mutect2, varscan2
- DIDO1 | c.1034C>G p.A345G | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as rs750135382, COSV99825538; called by muse, mutect2, varscan2
- DLGAP2 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV70093241; called by muse, mutect2, varscan2
- DNAH9 | c.6595G>T p.G2199* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99305379; called by muse, mutect2, varscan2
- DNHD1 | c.13378G>A p.V4460M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV99599913; called by muse, mutect2, varscan2
- DPP7 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs1245423672, COSV100857339, COSV100857439; called by muse, mutect2, varscan2
- DSCAM | c.5077G>T p.E1693* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV101259793; called by muse, mutect2, varscan2
- EFTUD2 | c.2033C>T p.T678M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781402078, CM162380, COSV101274536; called by muse, mutect2, varscan2
- ELF4 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100257317; called by muse, mutect2, varscan2
- ELL | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs575679241, COSV53214210, COSV99443050; called by muse, mutect2, varscan2
- ELOVL4 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV100876236; called by muse, mutect2, varscan2
- ERCC6 | c.4474T>G p.Y1492D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100875861; called by muse, mutect2, varscan2
- FADS1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs201926122, COSV100650239; called by muse, mutect2, varscan2
- FAM50B | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs760313884, COSV66654959; called by muse, mutect2, varscan2
- FAT3 | c.4688G>A p.S1563N | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV53161414, COSV99964844; called by muse, mutect2
- FBF1 | c.719C>T p.T240M (on ENST00000586717; = p.T254M on NM_001319193.1) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs577960184, COSV100045006; called by muse, mutect2, varscan2
- FGB | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as rs141881199, COSV57418827; called by muse, mutect2, varscan2
- FRMD5 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV101296409; called by muse, mutect2, varscan2
- GALNT15 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544070622, COSV100327561; called by muse, mutect2, varscan2
- GALNT18 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1040327384, COSV99924337; called by muse, mutect2, varscan2
- GALNTL6 | c.739A>G p.N247D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV101560226; called by muse, mutect2, varscan2
- GATAD2A | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99390027; called by muse, mutect2, varscan2
- GPHB5 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV100030191; called by muse, mutect2
- GPLD1 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs773905050, COSV100014919; called by muse, mutect2, varscan2
- GRIK2 | c.1900A>G p.R634G | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100025167; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN3A | c.2285C>A p.A762E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62451231; called by muse, mutect2, varscan2
- GSPT2 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61214793; called by muse, mutect2, varscan2
- GTPBP1 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV99323069; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs750293240, COSV55140417; called by pindel, varscan2
- HCFC2 | c.1694C>T p.T565M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs370973683; called by muse, mutect2, varscan2
- HIVEP3 | c.1159G>T p.G387W | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912295; called by muse, mutect2, varscan2
- HSPA12A | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs781918083, COSV65023925; called by muse, mutect2, varscan2
- HTRA2 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs138971069; called by muse, mutect2, varscan2
- INTU | c.2400C>G p.F800L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100080686; called by muse, varscan2
- IQCN | c.2857del p.A953Pfs*96 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as rs781149862; called by mutect2, pindel
- ITGAM | c.1441del p.H481Ifs*45 (on ENST00000648685 / NM_001145808.2; = p.H481Ifs*44 on NM_000632.4) | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as rs1303173835; called by mutect2, pindel, varscan2
- KATNAL2 | c.529G>A p.E177K (on ENST00000356157 / NM_001353899.1; = p.E105K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99796366; called by muse, mutect2, varscan2
- KCND3 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1408698527, COSV56187517; called by muse, mutect2, varscan2
- KCNJ4 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV57857435; called by muse, mutect2, varscan2
- KLHL18 | c.1369T>G p.W457G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99230775; called by muse, mutect2, varscan2
- KMT2B | c.1656dup p.K553Qfs*46 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | catalogued as rs775294431; called by mutect2, varscan2
- KMT2E | c.4504G>A p.A1502T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99996141; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 48/168 reads (29%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- L1CAM | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); catalogued as CM064088, COSV100649046; called by muse, mutect2, varscan2
- LALBA | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.182); catalogued as COSV99974388; called by muse, mutect2, varscan2
- LAMA5 | c.3854C>T p.A1285V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV99439382; called by muse, mutect2, varscan2
- LDB2 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1029147757, COSV58766726; called by muse, mutect2, varscan2
- LEMD2 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as COSV99540614; called by muse, mutect2, varscan2
- MAGEA11 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100290459; called by muse, mutect2, varscan2
- MAOA | c.1440C>T p.D480= | Splice Region (SNP) | VAF 25/91 reads (27%) | catalogued as rs367715125, COSV58641438; called by muse, mutect2, varscan2
- MAP1S | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100140994; called by muse, mutect2
- MEGF8 | c.8129C>T p.A2710V (on ENST00000251268 / NM_001271938.2; = p.A2643V on NM_001410.3) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.225); catalogued as rs1352725558, COSV99235721; called by muse, mutect2, varscan2
- MFAP3 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.118); catalogued as rs761733582, COSV59455932; called by muse, mutect2, varscan2
- MGAT5B | c.1573C>A p.R525S (on ENST00000569840 / NM_001199172.2; = p.R523S on NM_144677.3) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100047814; called by muse, mutect2, varscan2
- MKLN1 | c.1934A>G p.E645G | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as COSV100759786; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 11/45 reads (24%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MORN3 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100804468; called by muse, mutect2
- MUC16 | c.12843G>A p.M4281I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV101199319; called by muse, mutect2, varscan2
- MUC5B | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.475); catalogued as rs757427396, COSV101500259; called by muse, mutect2, varscan2
- MYOM3 | c.49del p.Q17Rfs*57 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs532144295; called by mutect2, pindel, varscan2
- MYSM1 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774297380, COSV68977213; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs747914168; called by mutect2, varscan2
- NEUROD1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.334); catalogued as COSV99716824; called by muse, mutect2, varscan2
- NIPAL3 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs761862441, COSV99135213; called by muse, mutect2, varscan2
- NOS1 | c.2027dup p.C677Lfs*38 | Frame Shift Ins (INS) | VAF 28/92 reads (30%) | catalogued as rs746543323; called by mutect2, varscan2
- NOS2 | c.1945G>T p.G649W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58228516; called by muse, mutect2, varscan2
- NUFIP2 | c.1777T>G p.L593V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV99837364; called by muse, mutect2, varscan2
- NUMA1 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100706052; called by muse, mutect2, varscan2
- NYAP1 | c.545dup p.G183Rfs*16 | Frame Shift Ins (INS) | VAF 19/79 reads (24%) | catalogued as rs751811587; called by mutect2, pindel, varscan2
- OBSL1 | c.4181G>A p.R1394H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs769302847, COSV99522637; ClinVar: uncertain significance; called by muse, mutect2
- OR10A4 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101139492; called by muse, mutect2, varscan2
- OR2A14 | c.859del p.L287* | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs1445635164; called by mutect2, pindel, varscan2
- OSR2 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as COSV99882489; called by muse, mutect2
- PALLD | c.1063_1065del p.T355del | In Frame Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs1182527611; called by pindel, varscan2
- PARP8 | c.2138T>A p.V713D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99890931; called by muse, mutect2, varscan2
- PCNT | c.7726T>C p.C2576R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100855386; called by muse, mutect2, varscan2
- PDCD10 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs753128265, COSV101208524; called by muse, mutect2, varscan2
- PER3 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100728307; called by muse, mutect2, varscan2
- PINX1 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100134790; called by muse, mutect2, varscan2
- PITX2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as rs373848340; called by muse, mutect2, varscan2
- PLAT | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs559494707, COSV99535118; called by muse, mutect2, varscan2
- POLD1 | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101486825; called by muse, mutect2, varscan2
- POLD1 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs146344351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPM1M | c.624C>A p.D208E (on ENST00000296487; = p.D369E on NM_144641.4) | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99626156; called by muse, mutect2
- PPP1R13B | c.2255T>C p.M752T | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99158450; called by muse, mutect2
- PPP6R1 | c.2034G>C p.E678D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100497569; called by muse, mutect2, varscan2
- PRDM10 | c.3431C>T p.T1144I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58800428; called by muse, mutect2, varscan2
- PRX | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as rs145790961; ClinVar: uncertain significance; called by muse, mutect2
- PSPN | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs368060064; called by muse, mutect2
- PTEN | c.878del p.G293Efs*14 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV64306603; called by mutect2, pindel, varscan2
- PTPN23 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99650492; called by muse, mutect2, varscan2
- PTPRG | c.4337G>T p.*1446Lext*4 | Nonstop Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99874344; called by muse, mutect2, varscan2
- RABGEF1 | c.373G>T p.G125* (on ENST00000439720 / NM_001287061.2; = p.G112* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99534748; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs762006287; called by mutect2, varscan2
- REXO5 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as rs746852256, COSV54472009; called by muse, mutect2, varscan2
- RFPL3 | c.854C>A p.P285H (on ENST00000249007 / NM_001098535.1; = p.P256H on NM_006604.2) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV99967039; called by muse, mutect2
- RHBDL3 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99283648; called by muse, mutect2, varscan2
- RNF31 | c.2884C>T p.R962W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs750039238, COSV100138121; called by muse, mutect2, varscan2
- ROCK2 | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99837260; called by muse, mutect2, varscan2
- RRAGB | c.509G>A p.C170Y (on ENST00000262850 / NM_016656.4; = p.C142Y on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99469250; called by muse, mutect2, varscan2
- RRP12 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV59668809; called by muse, mutect2, varscan2
- RSBN1 | c.1390T>A p.Y464N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99793130; called by muse, mutect2, varscan2
- RTL6 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV100373750; called by muse, mutect2, varscan2
- RYR2 | c.3434G>A p.W1145* | Nonsense Mutation (SNP) | VAF 8/206 reads (4%) | catalogued as COSV100769567; called by muse, mutect2
- SAMD3 | c.229A>C p.K77Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100148207; called by muse, mutect2, varscan2
- SART3 | c.1553T>C p.M518T (on ENST00000228284; = p.M500T on NM_014706.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV99934022; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCN3A | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99326563; called by muse, mutect2
- SCNN1G | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55600097; called by muse, mutect2
- SH3GLB1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs768566057, COSV100990762; called by muse, mutect2, varscan2
- SLC12A2 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1400086831, COSV99320949; called by muse, mutect2, varscan2
- SLC15A4 | c.1374C>G p.Y458* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99903529; called by muse, mutect2, varscan2
- SLC44A2 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59836476; called by muse, mutect2
- SLC5A9 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99361580; called by muse, mutect2, varscan2
- SLC7A6 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs546003282, COSV99546535; called by muse, mutect2, varscan2
- SLITRK1 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs905653392, COSV65677061; called by muse, mutect2, varscan2
- SMG1 | c.7892G>C p.R2631P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101245700, COSV67169154; called by muse, mutect2
- SNCAIP | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs146515227; called by muse, mutect2, varscan2
- SNPH | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs879326174, COSV101118676; called by muse, mutect2, varscan2
- SPATA31E1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs534832110, COSV57792634; called by muse, mutect2, varscan2
- SREBF2 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100761389; called by muse, mutect2, varscan2
- SSBP4 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99526043; called by muse, mutect2, varscan2
- STAMBP | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs747329455, COSV100277666; called by muse, mutect2, varscan2
- SUCNR1 | c.19T>C p.W7R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100751729; called by muse, mutect2, varscan2
- TAS1R3 | c.2478del p.E827Sfs*31 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs1557659353; called by mutect2, pindel, varscan2
- TCF7L2 | c.1645A>G p.M549V (on ENST00000355995 / NM_001367943.1; = p.M526V on NM_030756.5) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV99525573; called by muse, mutect2, varscan2
- TEAD2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs554567910, COSV99678656, COSV99678822; called by mutect2, varscan2
- TENM1 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV100949759; called by muse, mutect2, varscan2
- THSD7B | c.4699G>A p.A1567T (on ENST00000272643; = p.A1565T on NM_001316349.2) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs367680913, COSV99748669; called by muse, mutect2, varscan2
- TICAM1 | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as COSV99941076; called by muse, mutect2, varscan2
- TMEM131 | c.4724C>G p.S1575C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV99487453; called by muse, mutect2, varscan2
- TMEM132E | c.2083G>A p.A695T (on ENST00000321639; = p.A785T on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100396012, COSV100396157; called by muse, mutect2, varscan2
- TMEM161A | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1355175616, COSV99365461; called by muse, mutect2, varscan2
- TMTC3 | c.2274dup p.C759Mfs*3 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs1304750530; called by mutect2, varscan2
- TNP2 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV100449509; called by muse, mutect2
- TNPO3 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748991005, COSV55280357; called by muse, mutect2, varscan2
- TNS2 | c.845G>A p.R282Q (on ENST00000314250 / NM_170754.4; = p.R292Q on NM_015319.2) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745840449, COSV58574871; called by muse, mutect2, varscan2
- TRIM4 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1036689187, COSV100584252; called by muse, mutect2, varscan2
- TSC2 | c.1184G>A p.C395Y | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.997); catalogued as rs1026632436, COSV99553709; ClinVar: uncertain significance; called by muse, varscan2
- TSN | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101067477; called by muse, mutect2, varscan2
- TSPAN14 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs374281205; called by mutect2, varscan2
- TTN | c.61898G>A p.R20633H (on ENST00000591111; = p.R13209H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | PolyPhen probably damaging (0.998); catalogued as rs772979195, COSV60298564; called by muse, mutect2, varscan2
- TUT7 | c.161del p.K54Rfs*3 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs369091628; called by mutect2, pindel, varscan2
- UBE2B | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99530269; called by muse, mutect2, varscan2
- UBR1 | c.2432+1G>T p.X811_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99317048; called by muse, mutect2, varscan2
- UNC13C | c.4241G>T p.G1414V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52850088, COSV99515361; called by muse, mutect2, varscan2
- USP22 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.041); catalogued as COSV99820224; called by muse, mutect2, varscan2
- VPS13A | c.4526C>T p.A1509V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100652541; called by muse, mutect2, varscan2
- WBP1 | c.551dup p.H185Sfs*5 | Frame Shift Ins (INS) | VAF 20/91 reads (22%) | catalogued as rs547055147; called by mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK4 | c.1822dup p.V608Gfs*7 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs762079039; called by mutect2, varscan2
- ZBTB7C | c.403del p.E135Rfs*87 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | catalogued as rs747456682, COSV59688820; called by mutect2, pindel, varscan2
- ZFHX3 | c.8608G>C p.A2870P | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.202); catalogued as COSV99197321; called by muse, mutect2
- ZMYND12 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV100999800; called by muse, mutect2, varscan2
- ZNF439 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100397451; called by muse, mutect2, varscan2
- ZNF527 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV100648723, COSV62235453; called by muse, mutect2, varscan2
- ZNF549 | c.1588G>T p.E530* (on ENST00000376233 / NM_001199295.2; = p.E517* on NM_153263.2) | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as COSV99558490; called by muse, mutect2
- ZNF585B | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as rs776981729, COSV100459401; called by muse, mutect2, varscan2
- ZNF83 | c.509T>G p.I170S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99991312; called by muse, mutect2, varscan2
- ZSCAN4 | c.1115T>C p.M372T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99989922; called by muse, mutect2, varscan2
- ACACA | c.4550C>T p.T1517M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACAT1 | c.233del p.K78Rfs*9 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | called by mutect2, varscan2
- ACO2 | c.1395_1397del p.K465del | In Frame Del (DEL) | VAF 10/34 reads (29%) | called by pindel, varscan2
- ADGRV1 | c.6338dup p.N2113Kfs*2 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- ALPL | c.1398del p.M467Wfs*17 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.3859del p.D1287Tfs*78 (on ENST00000458649 / NM_001367468.1; = p.D1197Tfs*78 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/112 reads (35%) | called by mutect2, pindel, varscan2
- ARID4B | c.1892del p.N631Mfs*5 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- CCDC178 | c.1225dup p.S409Kfs*3 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- CLCA3P | n.466G>T | Splice Region (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- COL12A1 | c.8889del p.R2964Gfs*113 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- DGCR6L | c.481del p.V161Wfs*6 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- DOCK11 | c.2197del p.Y733Ifs*3 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- FAM98A | c.399del p.A134Lfs*13 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- FCGBP | c.3355G>A p.A1119T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.413); called by muse, mutect2
- FCGBP | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FOXJ3 | c.1132_1133del p.Q378Afs*71 | Frame Shift Del (DEL) | VAF 39/156 reads (25%) | called by pindel, varscan2
- GAB2 | c.1068del p.K357Sfs*70 (on ENST00000361507 / NM_080491.3; = p.K319Sfs*70 on NM_012296.3) | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | called by mutect2, pindel, varscan2
- HNRNPH1 | c.629dup p.Y210* | Nonsense Mutation (INS) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- IGLV3-10 | c.147del p.K49Nfs*43 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | called by mutect2, pindel, varscan2
- KCNIP3 | c.496_498del p.K166del | In Frame Del (DEL) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- KRT73 | c.47del p.G16Afs*102 | Frame Shift Del (DEL) | VAF 42/153 reads (27%) | called by mutect2, pindel, varscan2
- LRP1B | c.12877dup p.C4293Lfs*41 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- MOSPD1 | c.16del p.R6Dfs*5 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- NFATC3 | c.1962del p.K654Nfs*48 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- POLN | c.1304del p.L435Wfs*3 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- PPP1R12A | c.882del p.K294Nfs*8 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- PXN | c.971del p.P324Lfs*22 (on ENST00000228307 / NM_001080855.3; = p.P290Lfs*22 on NM_002859.4) | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- RAI1 | c.195del p.S67Lfs*79 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- REXO5 | c.1544del p.N515Ifs*7 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- ROCK1 | c.3138_3139del p.K1047Ifs*14 | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | called by pindel, varscan2
- SLC2A4 | c.304_306del p.I102del | In Frame Del (DEL) | VAF 14/55 reads (25%) | called by pindel, varscan2
- SLC45A4 | c.2102_2103del p.V701Gfs*72 (on ENST00000517878 / NM_001286646.2; = p.V650Gfs*106 on NM_001080431.2) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- SOX17 | c.1219dup p.Y407Lfs*7 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- TENT2 | c.596del p.L199Wfs*6 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- TRERF1 | c.1830del p.S611Pfs*104 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel, varscan2
- UBR5 | c.6360dup p.E2121Rfs*13 | Frame Shift Ins (INS) | VAF 38/129 reads (29%) | called by mutect2, varscan2
- USP36 | c.3239del p.K1080Rfs*31 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- ZNF396 | c.426del p.F142Lfs*7 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel
- ZNF84 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ABCF3 | c.195C>T p.C65= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs781029520, COSV99490515; called by muse, mutect2, varscan2
- ABCG8 | c.585G>A p.L195= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV99699693; called by muse, mutect2
- ACSM5 | c.1461G>A p.V487= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs770595649; called by muse, mutect2, varscan2
- ANKRD24 | c.3288G>A p.Q1096= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs775082696, COSV99517351; called by muse, mutect2, varscan2
- AR | c.90G>A p.V30= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV101017978; called by muse, mutect2, varscan2
- ARHGEF11 | c.1278G>A p.G426= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100809958; called by muse, mutect2, varscan2
- ARMC3 | c.1527T>C p.G509= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99957844; called by muse, mutect2, varscan2
- ARPC5L | c.372C>T p.S124= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs145806785; called by muse, mutect2, varscan2
- ASTN2 | c.1218C>T p.D406= (on ENST00000313400 / NM_001365069.1; = p.D355= on NM_014010.5) | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs373796089; called by muse, mutect2, varscan2
- ATP7B | c.2979G>A p.T993= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs200656411, COSV54439477; called by muse, mutect2, varscan2
- BASP1 | c.672C>T p.T224= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100493686, COSV100493878; called by muse, varscan2
- CASP8 | c.1230T>C p.V410= (on ENST00000432109 / NM_033355.3; = p.V427= on NM_001228.4) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99630121; called by muse, mutect2, varscan2
- CPTP | c.99T>C p.I33= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100028215; called by muse, mutect2, varscan2
- CSF2RB | c.600G>A p.E200= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV99453713; called by muse, mutect2, varscan2
- CUZD1 | c.714G>A p.S238= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs201913985, COSV59025502; called by muse, mutect2, varscan2
- DDX42 | c.78G>A p.K26= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100834896; called by muse, mutect2, varscan2
- DENND1C | c.1602T>C p.P534= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100375263; called by muse, mutect2, varscan2
- DENND2B | c.3045C>A p.S1015= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs151224923, COSV100567397; called by muse, mutect2, varscan2
- DPP10 | c.118C>T p.L40= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100062748; called by muse, mutect2, varscan2
- DUS1L | c.60C>T p.V20= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs772411249, COSV60785540; called by muse, mutect2, varscan2
- FAM104B | c.243G>A p.L81= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100146034; called by muse, mutect2, varscan2
- FAM149A | c.1674G>A p.Q558= (on ENST00000356371 / NM_001367768.2; = p.Q267= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV57031575; called by muse, mutect2, varscan2
- FAM24A | c.90G>A p.V30= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100925075; called by muse, mutect2
- FAT1 | c.9924T>C p.T3308= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV101499288; called by mutect2, varscan2
- FBXW9 | c.843C>T p.Y281= (on ENST00000587955; = p.Y291= on NM_032301.3) | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs771974745, COSV66710162; called by muse, mutect2, varscan2
- FCHSD1 | c.870T>C p.P290= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101447549; called by muse, mutect2, varscan2
- FRMD8 | c.681G>A p.E227= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1178968934, COSV100454667; called by muse, mutect2
- FUT6 | c.735C>T p.A245= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1273494625, COSV99744501; called by muse, mutect2
- HAS1 | c.1386G>A p.S462= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1315676777, COSV99708342; called by muse, mutect2
- HEATR9 | c.903G>A p.Q301= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- IL16 | c.75C>A p.L25= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100267413; called by muse, mutect2, varscan2
- INSRR | c.477G>A p.Q159= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100947408; called by muse, mutect2, varscan2
- INTS1 | c.2520G>C p.G840= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs765933412, COSV67178941; called by muse, mutect2, varscan2
- LMTK2 | c.1518G>A p.P506= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs151118353; called by muse, mutect2, varscan2
- MACF1 | c.13237C>T p.L4413= (on ENST00000372915; = p.L2346= on NM_012090.5) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99243466; called by muse, mutect2, varscan2
- MED12 | c.5727G>A p.Q1909= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100377403; called by muse, mutect2, varscan2
- MGAT5B | c.1083C>T p.F361= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs753876495, COSV56927914; called by muse, mutect2, varscan2
- MOB3B | c.138G>A p.A46= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs373218305; called by muse, mutect2, varscan2
- MYO18A | c.5034T>C p.S1678= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100572157; called by muse, mutect2, varscan2
- NRBP1 | c.225T>C p.N75= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99274940; called by muse, mutect2
- OR2L8 | c.424C>T p.L142= | Silent (SNP) | VAF 18/189 reads (10%) | catalogued as COSV61725625; called by muse, mutect2, varscan2
- OR51G1 | c.250C>T p.L84= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100429204; called by muse, mutect2, varscan2
- OSBPL3 | c.144C>A p.T48= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100513957; called by muse, mutect2, varscan2
- PHOX2B | c.600C>A p.P200= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as CD062207, COSV99891074; called by muse, varscan2
- PHRF1 | c.3762G>A p.P1254= (on ENST00000264555 / NM_001286581.2; = p.P1253= on NM_020901.4) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs755955028, COSV99199897; called by muse, mutect2, varscan2
- PKM | c.585G>T p.T195= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100064722; called by muse, mutect2
- PKP2 | c.231T>G p.L77= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99297558; called by muse, mutect2, varscan2
- PNPLA6 | c.1713C>T p.C571= (on ENST00000414982 / NM_001166111.2; = p.C523= on NM_006702.5) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1376335368, COSV99653524; called by muse, mutect2, varscan2
- POMT1 | c.319C>T p.L107= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100586329; called by muse, mutect2, varscan2
- PSAT1 | c.906T>C p.N302= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1476158627, COSV100716570; called by muse, mutect2, varscan2
- PTPN20 | c.597C>T p.R199= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs1338854771; called by muse, mutect2, varscan2
- PTPRH | c.456C>T p.Y152= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs148979033; called by muse, mutect2, varscan2
- RAB39B | c.414C>T p.A138= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV65624385, COSV65624954; called by muse, mutect2, varscan2
- RAB6D | c.717A>G p.S239= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs367878308; called by muse, mutect2, varscan2
- RFX1 | c.2340C>T p.R780= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99585999; called by muse, mutect2, varscan2
- RPL7 | c.639G>A p.L213= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1307611192, COSV99536264; called by muse, mutect2, varscan2
- SEC16A | c.318C>A p.P106= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99257412; called by muse, mutect2
- SECISBP2 | c.87G>A p.G29= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as COSV100068828; called by muse, mutect2, varscan2
- SEMA4D | c.2136C>A p.I712= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV100358208, COSV59390968; called by muse, mutect2, varscan2
- SEMA5A | c.2526C>T p.G842= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs996996362, COSV66789140; called by muse, mutect2, varscan2
- SLC17A7 | c.1326C>T p.N442= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs971797832, COSV55548445; called by muse, mutect2, varscan2
- SLC22A11 | c.345C>T p.D115= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs531709254, COSV100102283; called by muse, mutect2, varscan2
- SMPD3 | c.858C>T p.D286= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs145717053, COSV99545564; called by muse, mutect2, varscan2
- SOST | c.37C>T p.L13= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100059646; called by muse, mutect2, varscan2
- SPIN4 | c.498G>A p.T166= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV58737779; called by muse, mutect2, varscan2
- STKLD1 | c.1740G>A p.A580= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs147235884; called by muse, mutect2, varscan2
- TCOF1 | c.1605A>G p.S535= (on ENST00000377797 / NM_001135243.1; = p.S458= on NM_000356.4) | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100077246; called by muse, mutect2, varscan2
- TMPRSS4 | c.36C>T p.N12= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101449371; called by muse, mutect2
- TNC | c.1641C>T p.C547= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs149491853; called by muse, mutect2, varscan2
- UBXN10 | c.24T>C p.N8= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100907770; called by muse, mutect2
- UIMC1 | c.342T>C p.I114= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV101022105; called by muse, mutect2, varscan2
- WDR35 | c.2280G>A p.T760= (on ENST00000345530 / NM_001006657.2; = p.T749= on NM_020779.4) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs549934040, COSV99853077; called by muse, mutect2, varscan2
- WLS | c.1572T>C p.H524= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99259415; called by muse, mutect2
- ZNF28 | c.1914T>C p.N638= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100354434; called by muse, mutect2, varscan2
- ZNF527 | c.1104C>T p.S368= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV62234339; called by muse, mutect2, varscan2
- DDX41 | c.*946C>T | 3'UTR (SNP) | VAF 14/38 reads (37%) | catalogued as rs1195314927, COSV100394408, COSV57254467; called by muse, mutect2, varscan2
- DENND10P1 | n.931C>A | RNA (SNP) | VAF 40/140 reads (29%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23265C>T | Intron (SNP) | VAF 42/142 reads (30%) | catalogued as COSV100530145; called by muse, mutect2, varscan2
